TCGA case TCGA-B5-A11X — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Epithelial Neoplasms, NOS; Primary site: Corpus uteri; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f70a64a8-3faa-468a-a6f3-4815eb01e5a3

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Carcinoma, undifferentiated, NOS (the primary disease): ICD-O-3 morphology code: 8020/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,217 days); Year of diagnosis: 2010; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIIC2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 596 days (1.6 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 5.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 100.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 5; Lymph nodes tested: 5.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 65 days; Days to treatment end: 176 days; Number of cycles: 6; Prescribed dose: 5; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 65 days; Days to treatment end: 176 days; Number of cycles: 6; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Temsirolimus; Treatment intent type: Adjuvant; Days to treatment start: 86 days; Days to treatment end: 258 days; Number of cycles: 8; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Recurrent Disease; Days to treatment start: 412 days (1.1 years); Number of cycles: 8; Treatment outcome: Treatment Ongoing; Prescribed dose: 101; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Carcinoma, undifferentiated, NOS), site: Lymph node, NOS. Age at diagnosis: 67.4 years (24,614 days); Days to diagnosis: 397 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 337 days; Disease response: With Tumor.
- Day 397 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 397 days (1.1 years).
- Days to follow up: 596 days (1.6 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: Yes; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 71 kg; Height: 160 cm; BMI: 27.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B5-A11X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 530 mg.
  Slide TCGA-B5-A11X-01A-01-BSA: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
  Slide TCGA-B5-A11X-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
- Sample TCGA-B5-A11X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B5-A11X-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: Yes, I have taken menopausal hormone therapy in the past, but no longer do; Hypertension diagnosis: Yes; Pregnancies full term count: 2; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event site other: lymph nodes; New tumor event type: Metastatic; New tumor event surgery: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Regimen number: 2; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 596 days; disease-specific survival: no event (censored), 596 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 397 days.
